Somatic mutation profile of tumor specimen 0DWWN6 from CCDI case PBCPSB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.2 years (90 days).
Specimen 0DWWN6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e25321dd-2c34-41e9-8f0d-2239966de15c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWWMH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d8949fc-ac52-422a-ba92-7610e9d453f6

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMC1A | c.921C>A p.H307Q | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100447607; called by muse, mutect2
- MEGF11 | c.855C>T p.H285= | Silent (SNP) | VAF 98/250 reads (39%) | catalogued as rs145172692; called by muse, mutect2, varscan2
